Somatic mutation profile of tumor specimen 0DJPCR from CCDI case PBBWZD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 1.7 years (639 days).
Specimen 0DJPCR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90f368a1-bb8a-4b3b-a359-bca9f04ff01b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJPCK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41f8b729-270d-4eea-8fbf-df8407fae23d

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTOR | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 62/999 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55722922; called by muse, mutect2
- SAP130 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 74/581 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs139785439; called by muse, varscan2
- SORCS3 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 74/1080 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as rs751910484, COSV63793259; called by muse, mutect2
- UGT2B10 | c.771G>C p.M257I | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99607806; called by muse, varscan2
- ZNF800 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 210/719 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1049805866; called by muse, mutect2, varscan2
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 13/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CHRDL1 | c.1287C>A p.C429* (on ENST00000372045; = p.C435* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 194/294 reads (66%) | called by muse, mutect2, varscan2
- CSMD1 | c.7754T>C p.V2585A (on ENST00000520002; = p.V2584A on NM_033225.6) | Missense Mutation (SNP) | VAF 103/933 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SS18 | c.80A>T p.D27V | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ADAMTSL1 | c.3285C>G p.L1095= | Silent (SNP) | VAF 73/156 reads (47%) | catalogued as rs925868035; called by muse, mutect2, varscan2
- GUCY1A2 | c.370A>C p.R124= | Silent (SNP) | VAF 74/434 reads (17%) | called by muse, mutect2, varscan2
- ITGB2 | c.4C>T p.L2= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- MUC16 | c.15135C>T p.S5045= | Silent (SNP) | VAF 44/518 reads (8%) | catalogued as rs750267880; called by muse, mutect2
- GSX1 | c.-39G>T | 5'UTR (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
